Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2QA, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2QA-01A (Primary Tumor).

[page 1 of 3]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Patient with right thyroid nodule positive FNA for papillary carcinoma. Papillary thyroid carcinoma on FNA.

Specimens Submitted:

- 1: "Pparathyroid"; biopsy (fs)
- 2: Thyroid, right lobe; lobectomy
- 3: Thyroid, left lobe; lobectomy

DIAGNOSIS:

1. Parathyroid; biopsy:
- Benign parathyroid tissue.

2. Thyroid, right lobe; lobectomy:

Tumor Type:

Papillary carcinoma, follicular variant infiltrative

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 1.3 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades focally into peri-thyroid fibroadipose tissue

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Two separate foci of papillary microcarcinoma, 0.1 and 0.5 cm in greatest size.

ICD-0-3

Carcinoma, papillary, follicular variant
8340/3

Site: thyroid, NOS C73.9

hw
8/3/11

[page 2 of 3]
Non-Neoplastic Thyroid:

No abnormalities identified

Parathyroid Glands:

Not identified

Lymph Nodes:

One benign lymph node (0/1)

3. **Thyroid, left lobe; lobectomy:**

Tumor Type:

Papillary, microcarcinoma (occult sclerosing) variant
Two foci

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Size:

0.15 cm and 0.1 cm in greatest size respectively

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Thyroid:

No abnormalities identified

Parathyroid Glands:

Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh for frozen section labeled "exclude parathyroid" is a 0.2 cm red soft tissue fragment. The specimen is submitted in toto for frozen section.

Summary of sections:

FSC-frozen section control

[page 3 of 3]
2). The specimen is received fresh and is labeled "Right thyroid lobe, long stitch superior, short stitch isthmus". It consists of a thyroid lobe measuring 5.3 x 3 x 1.7 cm and weighing 8 g. The surface is disrupted in the posterior superior aspect. The lobe is inked black posterior and blue anterior. Serial sectioning reveals two lesions: 1.3 x 0.7 x 0.6 cm white solid nodule in superior/mid lobe abutting posterior margin (N1) and 0.5 x 0.3 x 0.2 cm solid white nodule in lower lobe (N2). The specimen is entirely submitted to include TPS from both nodules.

Summary of sections:

N1 - larger nodule
N2 - smaller nodule
RL - remaining lobe
I - isthmus

3). The specimen is received fresh and is labeled "Left thyroid lobe, stitch marks superior pole". It consists of a thyroid lobe measuring 4.3 x 2.8 x 1.4 cm and weighing 7.5 g. The lobe is inked black posterior and blue anterior. Serial sectioning reveals a 0.3 x 0.3 x 0.2 cm white fibrotic area abutting the posterior margin in the mid lobe. The remaining cut surface is unremarkable. The specimen is entirely submitted.

Summary of sections:

L - lesion
RL - remaining lobe

Summary of Sections:

Part 1: "Pparathyroid"; biopsy (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: Thyroid, right lobe; lobectomy

Block	Sect. Site	PCs
1	I	3
2	N1	4
1	N2	1
3	RL	3

Part 3: Thyroid, left lobe; lobectomy

Block	Sect. Site	PCs
1	L	1
6	RL	6

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Exclude parathyroid (fs): Parathyroid tissue
Permanent diagnosis: same

Source: NCI Genomic Data Commons file 941ad713-b3d1-46c7-94df-224634ed0c90 (TCGA-DJ-A2QA.E3CC8058-B202-4433-8597-6BD196D04AAC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).